Somatic mutation profile of tumor specimen 0DRY7W from CCDI case PBCGJV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Retinoblastoma, NOS; Tissue or organ of origin: Retina; Age at diagnosis: 2.2 years (809 days).
Specimen 0DRY7W: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a5f95fb-d9b2-470d-8ce2-12953a245b13.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRY86 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/44ffc610-e174-4ee5-93fb-e3d9c3749661

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TRRAP | c.3742G>A p.E1248K | Missense Mutation (SNP) | VAF 31/310 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.214); catalogued as COSV62841802; called by muse, mutect2, varscan2
- MSX1 | c.828C>T p.G276= | Silent (SNP) | VAF 170/397 reads (43%) | catalogued as rs376186261; called by muse, mutect2, varscan2
- TMC3 | c.1749G>A p.A583= | Silent (SNP) | VAF 110/287 reads (38%) | catalogued as rs758084232, COSV63923336; called by muse, mutect2, varscan2
